Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7750, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7750-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

DIAGNOSIS:

A. Prostate, vas deferens and seminal vesicles, prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 4.5 x 4.0 x 3.5 cm.
3. Tumor quantitation: Tumor occupies roughly 10 to 15% of prostate volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Not identified.

Surgical Margin Status:

1. Inked margins negative for tumor.
2. Apex and bladder base margins negative.

Lymph Node Status:

1. No lymph nodes present.

Other:

1. pTNM stage: pT2cNX.

B. Left lateral margin, biopsy:

Negative for malignancy.

C. Urethral margin, biopsy:

Extensive cautery artifact without definitive malignancy identified.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: ■ year old male with prostate cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Prostate, vas deferens, seminal vesicle
- B. Left lateral margin
- C. Urethral margin

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three formalin filled containers labeled with the patient's name

Container A is additionally labeled "prostate, vas deferens, seminal vesicle" and contains a 41.4 gm, 4.5 x 4.0 x 3.5 cm prostate received with attached bilateral adnexa having overall dimensions of 4.0 x 3.8 x 1.0 cm. The capsule is pink-tan and shaggy. It is inked as follows: right side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sections from apex to base to reveal a pink-tan focally cystic cut surface with diffuse periurethral nodularity. A 0.5 cm, ill defined, yellow-tan lesion is present within the left posterior quadrant near the apex. This nodule approaches to within 0.4 cm of the inked capsule. No additional lesions are identified. Also received in the same container is a 4.0 cm in length by 0.4 cm in diameter, pink-tan, cylindrical soft tissue consistent with vas deferens

[page 2 of 2]
A1-18 labels are designated as follows: 1 right prostate/seminal vesicle junction; 2 left prostate/seminal vesicle junction; 3-4 apical margin, perpendicular; 5-6 base margin, perpendicular; 7-9 right anterior, apex to base; 10-12 right posterior, apex to base; 13-15 left anterior, apex to base; 16-18 left posterior, apex to base. Additionally, a yellow and green cassette are submitted for genomics research, each labeled [REDACTED].

Container B is additionally labeled "left lateral margin" and contains two pink-tan, rubbery, irregular soft tissues, each measuring 1.5 cm in greatest dimension. One tissue features a white clip at one edge. No designation is given to the clip. The clip is removed and the specimen is entirely submitted in cassette B label.

Container C is additionally labeled "urethral margin" and contains a 1.3 x 0.5 x 0.4 cm, pink-tan, diffusely cauterized, rubbery soft tissue. Entirely submitted in cassette C label.

Source: NCI Genomic Data Commons file 1f25f65a-fa58-463a-8f82-32da0f572547 (TCGA-HC-7750.F05D95FD-391D-49AB-8A2F-039110A654BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).